Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A290, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A290-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Not answered.

PROCEDURE: Total thyroidectomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION: No

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

ADDENDA:**Addendum****Molecular Anatomic Pathology Testing:**

Collection Date: _____

ICD-0-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, Nos C73.9

lw
5/25/11**Block I:**

- A. **BRAF V600E** mutation IDENTIFIED.
- B. Mutations in **NRAS61**, **HRAS61**, **KRAS12/13** NOT identified.
- C. FISH test results are negative for **RET/PTC** rearrangement.

Note:

DNA was extracted in the amount sufficient for testing.

FINAL DIAGNOSIS:

THYROID, TOTAL THYROIDECTOMY (53.2 GRAMS) -

- A. **PAPILLARY THYROID CARCINOMA** WITH **TALL CELL** FEATURES (4.5 CM) LOCATED IN THE **LEFT LOBE**.
- B. TUMOR INVADIES **PERITHYROIDAL SKELETAL MUSCLE** AND EXTENDS TO MARGIN.
- C. **THREE (3) LYMPH NODES** WITH **METASTATIC PAPILLARY THYROID CARCINOMA** ATTACHED TO **LEFT LOBE** OF THYROID (3/3). (NO **EXTRANODAL SPREAD** IS SEEN)
- D. **NODULAR THYROID**.
- E. **ONE NORMOCELLULAR PARATHYROID GLAND** ATTACHED TO THE **LEFT LOBE** OF THE THYROID.
- F. **pT3N1MX**.

COMMENT:

Molecular studies have been ordered and the results will be reported in an addendum.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Left Lobe
TUMOR FOCALITY: Unifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 4.5 cm
HISTOLOGIC TYPE: Papillary carcinoma
PATHOLOGIC STAGING (pTNM): pT3

pN1a
Number of regional lymph nodes examined: 3
Number of regional lymph nodes involved: 3
pMX

MARGINS:

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Margin(s) Involved by carcinoma
Present

ADDITIONAL PATHOLOGIC FINDINGS: Other: **NODULAR THYROID**

IIQA Discrepancy		☒

Source: NCI Genomic Data Commons file 64f18f7f-234e-4113-a6aa-9c00d7c419f5 (TCGA-BJ-A290.270D1C48-B0EE-40AD-8E01-D8567CAC896D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).